Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8N, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8N-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

HISTOPATHOLOGY

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED] Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

SPECIMEN

RESECTION OF EYE AND EYE APPENDAGES

ENUCLEATED RIGHT EYE

CLINICAL DETAILS

Right eye choroidal melanoma and exudative retinal detachment.

MACROSCOPIC DESCRIPTION

A fresh intact right globe.

Dimensions: Axial 27.5mm Horizontal 25.5mm Vertical 25mm

Cornea Horizontal 11.25mm Vertical 11.5mm

Optic Nerve Fresh

On trans-illumination, a large shadow is seen measuring approximately 20mm ?? on the lateral side.

Plane of Section Horizontal

Intraocular description:

On opening, a large solitary ? shape is seen.

Query: Cilio choroidal mass seen.

Tumour Size LBD 15mm Height 12mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal anterior segment with an unremarkable cornea, a deep anterior chamber and open angles. The iris leaves are unremarkable. The lens shows advanced cataractous changes.

On one side of the eye, a large melanoma is arising from the ciliary muscle and body. This is bilobed and extends posteriorly into the adjacent choroid. In the central apical

ICD O 3
Melanoma, epithelioid & spindle
cell mixed 8770/3
Site @ Choroid C69.3
Op 5/30/14

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

part of the tumour, there is a small area of necrosis. The tumour is associated with disruption of the ciliary body processes and with a detachment of the retina. It is pigmented and consists of a mixture of cells, both epithelioid and spindle cells, with a dominance of the former cell type. The melanoma cells are immunoreactive for MelanA, CD117 and HSP-27 (score 1). The number of mitoses is approx. 21/40 high power fields.

The microvasculature of the melanoma is prominent, and closed loops are present in the tissue planes evaluated. The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in a moderate density. There is no evidence of scleral invasion or of extraocular growth. The optic nerve is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

FINAL DIAGNOSIS

Choroidal melanoma of epithelioid cell type.

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow as soon as these investigations are complete.

MOLECULAR GENETICS

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 3 of 3]
Department of Pathology			Page 3 of 3
HISTOPATHOLOGY REPORT Tel:			
Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

Normal chromosome 1,
monosomy 3,
normal chromosome 6
and gains in chromosome 8.

Taken together, these molecular data would place the patient in the high risk group with respect to the development of metastatic melanoma. Consideration of clinical features of the tumour is, however, also required.

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Source: NCI Genomic Data Commons file d2b149dc-be1a-4131-b73c-ad8b4c6c1190 (TCGA-VD-AA8N.ED92C74C-5F12-4163-8894-1F538D2451B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).